Gene-level copy-number profile of tumor specimen HCM-WCMC-0675-C67-02A from HCMI case HCM-WCMC-0675-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage X; Tumor grade: GX; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen HCM-WCMC-0675-C67-02A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 87690bf2-8cef-484b-bf86-b04308fba34b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0675-C67-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/62102595-1359-4d6a-83cf-f4852406fd21

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 203; copy number 2: 8,297; copy number 3: 22,193; copy number 4: 16,678; copy number 5: 8,568; copy number 6: 2,399; copy number 7: 333; copy number 8: 80; copy number 9: 98; copy number 10: 22; copy number 11: 6; copy number 12: 5; copy number 13: 13; copy number 19: 2; copy number 21: 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–3): RPS3AP15.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr16:2,090,195–2,090,284, 1 gene (within-gene range 0–1): MIR1225.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 560 genes in 60 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,995,211–161,470,523, 37 genes, copy number 7–10: F11R, AL591806.2, GLRX5P2, TSTD1, USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2, NIT1, DEDD, AL591806.1, UFC1, AL590714.1, USP21, PPOX, B4GALT3, ADAMTS4, NDUFS2, FCER1G, APOA2, TOMM40L, MIR5187, NR1I3, PCP4L1, MPZ, SDHC, CFAP126, AL592295.6, RRM2P2, AL592295.4, AL592295.5, RNU6-481P, AL592295.3, AL592295.1, AL592295.2.
- chr1:161,513,176–161,736,102, 16 genes, copy number 9 (within-gene range 6–9): AL590385.2, HSPA6, RPS23P10, FCGR3A, AL590385.1, FCGR2C, HSPA7, RPS23P9, FCGR3B, FCGR2B, AL451067.1, RPL31P11, Y_RNA, FCRLA, FCRLB, RN7SL466P.
- chr1:228,687,415–229,305,894, 10 genes, copy number 8 (within-gene range 5–8): FTH1P2, RHOU, AL078624.2, AL078624.1, ISCA1P2, LINC02814, AL162595.2, TMEM78, AL162595.1, RAB4A.
- chr1:234,527,887–234,980,804, 18 genes, copy number 9: LINC01354, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3.
- chr4:37,453,925–38,701,517, 22 genes, copy number 7: C4orf19, AC022463.1, AC027607.1, RELL1, Y_RNA, AC108022.1, PGM2, AC021106.2, AC021106.1, TBC1D1, PTTG2, PSME2P4, MRPS33P2, AC098680.1, LINC02513, AC024023.1, LINC01258, LINC01259, LINC02278, KLF3-AS1, AC021860.1, KLF3.
- chr5:34,651,457–34,958,964, 10 genes, copy number 9: AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21.
- chr6:26,017,032–26,240,793, 35 genes, copy number 9: H1-1, H3C1, H4C1, H4C2, H3C2, H2AC4, H2BC3, H2AC5P, H3C3, H1-2, HFE, H4C3, H1-6, H2BC4, H2AC6, H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P, H3C6, H2AC9P, H1-3, H4C6.
- chr6:158,765,741–158,864,502, 4 genes, copy number 8: EZR, EZR-AS1, OSTCP1, AL627422.2.
- chr7:17,299,295–17,467,256, 3 genes, copy number 8 (within-gene range 4–8): AC019117.3, SNORA63, AC019117.2.
- chr7:73,736,094–73,842,516, 4 genes, copy number 7: ABHD11, CLDN3, CLDN4, METTL27.
- chr8:40,104,169–40,172,612, 4 genes, copy number 10: AC087518.1, LINC02866, TCIM, AC022733.1.
- chr8:89,757,806–90,003,228, 6 genes, copy number 8 (within-gene range 5–8): RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN.
- chr8:100,257,060–101,492,499, 42 genes, copy number 7 (within-gene range 5–7): RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3.
- chr8:124,823,702–125,367,120, 11 genes, copy number 8 (within-gene range 5–8): LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P.
- chr8:132,685,007–133,409,107, 15 genes, copy number 7–9: TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6.
- chr8:140,657,900–141,060,596, 5 genes, copy number 8: PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1.
- chr8:142,670,308–142,736,927, 5 genes, copy number 11 (within-gene range 4–11): PSCA, LY6K, LNCOC1, THEM6, AC108002.1.
- chr10:5,412,557–5,632,566, 6 genes, copy number 7 (within-gene range 6–7): NET1, CALML5, CALML3-AS1, CALML3, AL732437.1, LASTR.
- chr10:103,967,140–104,029,233, 2 genes, copy number 7: SLK, RN7SL524P.
- chr11:64,223,799–64,372,215, 25 genes, copy number 7 (within-gene range 4–7): TRPT1, NUDT22, AP001453.1, DNAJC4, VEGFB, FKBP2, AP001453.3, PPP1R14B, PPP1R14B-AS1, AP001453.2, PLCB3, BAD, GPR137, KCNK4, KCNK4-TEX40, Y_RNA, CATSPERZ, ESRRA, TRMT112, PRDX5, AP003774.2, CCDC88B, MIR7155, RPS6KA4, MIR1237.
- chr11:65,422,774–65,506,516, 13 genes, copy number 13: NEAT1, AP000944.4, AP000944.3, AP000944.2, MIR612, AP000769.4, AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3.
- chr11:128,095,758–128,587,558, 5 genes, copy number 7: LINC02725, LINC02098, ETS1, MIR6090, ETS1-AS1.
- chr12:89,319,364–93,894,840, 81 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr12:114,504,876–116,277,693, 31 genes, copy number 7: RN7SKP216, AC069240.1, OSTF1P1, AC010177.1, Y_RNA, TBX3, AC026765.3, AC026765.4, AC026765.1, AC026765.2, AC009804.1, AC008125.1, AC078880.1, AC078880.3, AC078880.4, AC078880.5, AC078880.2, AC009803.2, AC009803.1, UBA52P7, RN7SL865P, AC009387.1, LINC02463, AC012157.1, AC012157.3, MED13L, AC012157.2, RNU6-1188P, MIR620, SNRPGP18, AC130895.1.
- chr13:31,952,580–32,031,639, 4 genes, copy number 8–9 (within-gene range 5–9): EEF1DP3, AC002525.1, Metazoa_SRP, FRY-AS1.
- chr13:48,053,323–48,599,436, 16 genes, copy number 8–10: MED4, MED4-AS1, POLR2KP2, ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462.
- chr13:72,703,693–73,661,891, 17 genes, copy number 7: RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr15:92,819,540–93,027,996, 4 genes, copy number 7 (within-gene range 3–7): CHASERR, AC013394.1, CHD2, MIR3175.
- chr16:27,224,994–27,314,101, 3 genes, copy number 7 (within-gene range 4–7): NSMCE1, NSMCE1-DT, AC106739.1.
- chr17:40,439,467–40,721,932, 14 genes, copy number 7–8: RPL23AP75, IGFBP4, AC018629.1, TNS4, AC004585.1, CCR7, AC004585.2, SMARCE1, AC073508.2, AC073508.3, KRT222, AC073508.1, KRT24, KRT223P.
- chr17:41,500,981–41,554,495, 6 genes, copy number 9: KRT13, AC019349.1, KRT15, MIR6510, KRT19, LINC00974.
- chr19:1,228,287–1,259,140, 4 genes, copy number 8–21 (within-gene range 5–21): CBARP, AC004221.1, ATP5F1D, MIDN.
- chr19:13,836,287–13,836,659, 3 genes, copy number 12: MIR24-2, MIR27A, MIR23A.
- chr19:45,406,644–45,478,828, 3 genes, copy number 7 (within-gene range 5–7): POLR1G, ERCC1, MIR6088.
- chr20:50,429,190–50,585,879, 7 genes, copy number 8: RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645.
- chr20:53,567,065–54,269,542, 11 genes, copy number 7 (within-gene range 4–7): ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1.
- chr21:43,414,483–43,812,567, 15 genes, copy number 9–10: SIK1, LINC00319, LINC00313, AP001048.1, HSF2BP, RPL31P1, H2BS1, MIR6070, RRP1B, PDXK, AP001052.1, CSTB, TMEM97P1, RRP1, AATBC.
- chr22:36,172,422–36,204,840, 7 genes, copy number 7: MTCO1P20, MTCO2P20, MTATP6P20, MTCO3P20, MTCYBP34, MTND1P10, APOL4.
- chr22:38,200,767–38,273,010, 4 genes, copy number 7: MAFF, TMEM184B, AL020993.1, RN7SL704P.
- chr22:46,049,478–46,069,891, 5 genes, copy number 8: PRR34, AL121672.3, PRR34-AS1, AL121672.1, AL121672.2.

Autosomal genes at a single copy (total copy number 1): 203. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
